Somatic mutation profile of tumor specimen 0DM4XH from CCDI case PBBYUE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, metastatic, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.7 years (5,376 days).
Specimen 0DM4XH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2123214b-b6e2-4469-adb1-39e8d2d9f353.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM4X1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e0ef5180-2d95-401d-a34b-03457bbca80c

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLA2G4C | c.791G>A p.G264D | Missense Mutation (SNP) | VAF 175/670 reads (26%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs778711130; called by muse, varscan2
- GAPVD1 | c.3047-32G>C | Intron (SNP) | VAF 62/228 reads (27%) | called by muse, varscan2
